Somatic mutation profile of tumor specimen TCGA-ET-A3BT-01A (aliquot TCGA-ET-A3BT-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 60.5 years (22,108 days).
Specimen TCGA-ET-A3BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f2c2ade-b047-4e9a-a1e3-d64fdc442432.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BT-10A (Blood Derived Normal), aliquot TCGA-ET-A3BT-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eabfce0-ecbb-49b9-beab-d693f31059d7

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCNT1 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV56063187; called by muse, mutect2, varscan2
- FAM187B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61200902; called by muse, mutect2, varscan2
- KRT35 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55842259; called by muse, mutect2, varscan2
- OR2T4 | c.946G>T p.V316L | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63543287; called by muse, mutect2, varscan2
- OR4C3 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV60583412; called by muse, mutect2, varscan2
- PEAK3 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV59700778; called by muse, mutect2, varscan2
- RNF7 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56421716; called by muse, mutect2, varscan2
- TMEM53 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs765679820, COSV59189728; called by muse, mutect2, varscan2
- TTC39C | c.575T>A p.L192* (on ENST00000317571 / NM_001135993.2; = p.L131* on NM_153211.4) | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV58215514; called by muse, mutect2, varscan2
- TTK | c.52A>G p.N18D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs757845279, COSV57881508; called by muse, mutect2, varscan2
- ZNF384 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs775320296, COSV100158491, COSV60528971; called by muse, mutect2, varscan2
- IGFBP5 | c.349del p.R117Vfs*31 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- KMT2E | c.2050dup p.I684Nfs*9 | Frame Shift Ins (INS) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- RNF128 | c.629dup p.V211Rfs*42 (on ENST00000255499 / NM_194463.2; = p.V185Rfs*42 on NM_024539.3) | Frame Shift Ins (INS) | VAF 40/112 reads (36%) | called by mutect2, varscan2
- DSC3 | c.819G>A p.P273= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs374250811; called by muse, mutect2, varscan2
- PPP4R1 | c.522C>T p.C174= (on ENST00000400556 / NM_001042388.3; = p.C157= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV53280357; called by muse, mutect2
- WASHC2A | c.1023C>T p.F341= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as rs551829472, COSV50954645; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.71A>T | RNA (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
